Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RO-01A (Primary Tumor).

[page 1 of 2]
PAGE: 1

RUN DATE:
RUN TIME:
BY:

Specimen Inquiry

PATIENT: ACCT #: LOC: U#: REG DR: DOB: AGE/SX: /F RM/BED: REG: STATUS: I TLLOC: DIS:

SPEC #:
STATUS:

Obtained:
Received:

Subm Dr:

CLINICAL HISTORY:
233.1

100-0-3
carcinoma, squamous cell, nonkeratinizing, NOS
8072/3

SPECIMEN/PROCEDURE:
1. CERVIX

Site: cervix, NOS C53.9

lw
9/8/11

IMPRESSION:
CERVICAL BIOPSY:

Squamous cell carcinoma, non-keratinizing invading fibromuscular connective tissue.

Dictated
Entered:

GROSS DESCRIPTION:

1. Received in formalin labeled with the patient's name and medical record number. Received is a pink to pale red-tan tissue fragment that is 0.7 x 0.5 x 0.4 cm. The specimen is entirely submitted in one cassette.

Dictated:
Entered:

COPIES TO:

No Primary or Family Physician
Undefined Provider

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
SPEC #:

Continued) Page: 2

CPT Codes:

CERVICAL BIOPSY/88305

ICD9 Codes:

180.9

Electronically Signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file 20522a70-4657-4e5f-b9fb-6addbdd663d5 (TCGA-EK-A2RO.49E0E89E-7DB0-4FFD-8246-1EF8E4308829.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).